Gene-level copy-number profile of tumor specimen C3N-00148-02 from CPTAC case C3N-00148, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.9 years (19,314 days).
Specimen C3N-00148-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fb088c64-524f-4b35-af82-dd4f7eec6368.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00148-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/c63ef218-d4f7-4862-be07-6e04743db801

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 517; copy number 1: 6,697; copy number 2: 45,388; copy number 3: 6,262; copy number 4: 22; copy number 7: 12; copy number 8: 6.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–31,109, 5 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–133,723, 3 genes, copy number 7–8 (within-gene range 4–8): OR4G11P, OR4F5, AL627309.1.
- chr1:131,025–522,928, 14 genes, copy number 7–8: CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:587,629–594,768, 1 gene, copy number 7: AC114498.1.

Autosomal genes at a single copy (total copy number 1): 4,357. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
